Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7QY, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7QY-01A (Primary Tumor).

ICD-O-3
Oligoastrocytoma, grade II 9382/3
Site: ^{CCCF} Brain, supratentorial NOS C71.0
path Brain, NOS C71.9
Q 9/27/13

untranslated original report
is housed at the BCR.

Criteria	W 9/11/13	No

Glial tumor of astrocytic + oligodendroglial
differentiation.
IDH2 R172K mutation + LOH 1p/19q present

Diagnosis:
oligoastrocytoma WHO grade II

Source: NCI Genomic Data Commons file 2aa15d38-6764-44cb-855b-de3c126f81a8 (TCGA-S9-A7QY.7833FCD6-2858-4428-9E9C-A8AEA10F42F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).